Somatic mutation profile of tumor specimen TCGA-A5-A1OG-01A (aliquot TCGA-A5-A1OG-01A-11D-A14G-09) from TCGA case TCGA-A5-A1OG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 65.6 years (23,956 days).
Specimen TCGA-A5-A1OG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f95b0a-6293-4541-a919-56f4a7ea2238.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A1OG-10A (Blood Derived Normal), aliquot TCGA-A5-A1OG-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1835bf-cb15-428b-86a1-882068279e35

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 30, Silent 6, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.312); catalogued as CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB1IP | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs746726119, COSV100774448; called by muse, mutect2, varscan2
- BCL11A | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100186368; called by muse, mutect2, varscan2
- BIN1 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99388459; called by muse, mutect2, varscan2
- BPTF | c.6727G>T p.G2243W | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100074385; called by muse, mutect2
- C20orf194 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99331403; called by muse, mutect2, varscan2
- CCDC89 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100320913, COSV57033437; called by muse, mutect2, varscan2
- CDC37L1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1161666290, COSV101116647; called by muse, mutect2
- CYP2S1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778416663, COSV59505219; called by muse, mutect2, varscan2
- DUOX2 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1383183726, COSV101199882; called by muse, mutect2, varscan2
- EME2 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs377305101, COSV99457379; called by muse, mutect2, varscan2
- HUWE1 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99473964; called by muse, mutect2, varscan2
- IGFL2 | c.349C>T p.R117C (on ENST00000377693 / NM_001135113.2; = p.R128C on NM_001002915.2) | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs544005376, COSV100890703; called by muse, mutect2, varscan2
- MEGF10 | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1554102007, COSV99175505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA35 | c.1986C>A p.H662Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.184); catalogued as COSV100863427; called by muse, mutect2, varscan2
- NCBP1 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100912670; called by muse, mutect2, varscan2
- PAGE1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); catalogued as rs369503230, COSV101093998; called by muse, mutect2, varscan2
- PLCH1 | c.2767A>G p.S923G (on ENST00000340059 / NM_001130960.2; = p.S915G on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100398078; called by muse, mutect2, varscan2
- PLXNB2 | c.4868C>G p.T1623R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100834271; called by muse, mutect2, varscan2
- RANBP3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as rs1490463714, COSV99222486; called by muse, mutect2, varscan2
- RBM3 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100618781; called by muse, mutect2, varscan2
- RHAG | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100006833; called by mutect2, varscan2
- RTL5 | c.1386T>A p.D462E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.018); catalogued as COSV101030303; called by muse, mutect2, varscan2
- TBX22 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100960931; called by muse, mutect2, varscan2
- TFAP2B | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53825294, COSV99540314; called by muse, mutect2, varscan2
- TPH1 | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100001059; called by muse, mutect2, varscan2
- TRAT1 | c.462C>G p.D154E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as rs774988510, COSV99849521; called by muse, mutect2, varscan2
- ZC3H4 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs945373292, COSV99452724; called by muse, mutect2, varscan2
- FRMPD2B | n.856G>T | Splice Region (SNP) | VAF 19/97 reads (20%) | called by mutect2, varscan2
- MUC2 | c.2758A>G p.I920V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FLNA | c.7668C>T p.D2556= (on ENST00000369850 / NM_001110556.2; = p.D2548= on NM_001456.3) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs782784577, COSV61043567; called by mutect2, varscan2
- MAMLD1 | c.2190G>A p.S730= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs782280266, COSV99476512; called by muse, mutect2, varscan2
- RAPGEF1 | c.2364C>T p.R788= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1350293317, COSV100940634; called by muse, mutect2, varscan2
- SIK2 | c.2079C>A p.A693= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100232366; called by muse, mutect2, varscan2
- SLC9A6 | c.1236A>G p.T412= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV100857944; called by muse, mutect2, varscan2
- WDR3 | c.138C>T p.H46= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100832347; called by muse, mutect2
